CCDI case PBBZYM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Malignant Lymphomas, NOS or Diffuse; Primary site: Lymph nodes.
https://portal.gdc.cancer.gov/cases/97b79974-cd5c-4af9-abdc-64cd069bb5d5

Demographics
Sex at birth: male.

Diagnoses (1)
1. Malignant lymphoma, non-Hodgkin, NOS: ICD-O-3 morphology code: 9591/3; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 14.4 years (5,259 days).

Biospecimens (2 samples)
- Sample 0DMEUA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DMEUJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
